Somatic mutation profile of tumor specimen TCGA-ZJ-AAXN-01A (aliquot TCGA-ZJ-AAXN-01A-11D-A42O-09) from TCGA case TCGA-ZJ-AAXN, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, large cell, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Age at diagnosis: 34.8 years (12,701 days).
Specimen TCGA-ZJ-AAXN-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 167045e8-4a60-4c41-8f72-c66b8838c3ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ZJ-AAXN-10A (Blood Derived Normal), aliquot TCGA-ZJ-AAXN-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/43476464-a109-4c5d-ae31-794fa35b4bd6

The open-access MAF lists 58 somatic variants for this specimen: 42 protein-altering or splice-affecting, 14 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Nonsense Mutation 3, 3'UTR 1, Splice Region 1, Frame Shift Ins 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRSK1 | c.1135dup p.R379Pfs*54 | Frame Shift Ins (INS) | VAF 44/92 reads (48%) | catalogued as rs746043904; called by mutect2, varscan2
- BTK | c.1019C>G p.P340R | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.755); catalogued as COSV100437573, COSV58124425; called by muse, mutect2, varscan2
- CACNA1F | c.3133C>A p.L1045M | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.662); catalogued as rs1557107470, COSV100544734; called by muse, mutect2, varscan2
- CELF4 | c.144G>A p.M48I | Missense Mutation (SNP) | VAF 26/38 reads (68%) | SIFT deleterious (0.03); PolyPhen benign (0.354); catalogued as COSV100611596; called by muse, mutect2, varscan2
- CENPJ | c.3745G>A p.D1249N | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99693067; called by muse, mutect2, varscan2
- CHORDC1 | c.567G>A p.M189I | Missense Mutation (SNP) | VAF 13/85 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); catalogued as COSV57706414; called by muse, mutect2, varscan2
- COG6 | c.949C>T p.Q317* | Nonsense Mutation (SNP) | VAF 21/47 reads (45%) | catalogued as COSV100742839; called by muse, mutect2, varscan2
- CYP11A1 | c.136C>A p.R46S | Missense Mutation (SNP) | VAF 7/37 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.816); catalogued as COSV99165984; called by muse, mutect2, varscan2
- DDX46 | c.475G>A p.E159K | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.899); catalogued as COSV100844869; called by muse, mutect2, varscan2
- DOCK4 | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs1411547516, COSV70322564; called by muse, mutect2, varscan2
- EYA3 | c.1253G>A p.R418H | Missense Mutation (SNP) | VAF 26/64 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1436190770, COSV100870241; called by muse, mutect2, varscan2
- FGFR1OP2 | c.535A>G p.I179V | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.51); catalogued as COSV99986895; called by muse, mutect2, varscan2
- FKBP15 | c.1706G>A p.R569Q | Missense Mutation (SNP) | VAF 36/65 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs532818858, COSV53040061; called by muse, mutect2, varscan2
- FLG | c.4687G>T p.E1563* | Nonsense Mutation (SNP) | VAF 28/129 reads (22%) | catalogued as COSV100911527, COSV64242286; called by muse, mutect2, varscan2
- GSPT2 | c.137C>T p.S46L | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); catalogued as COSV61214476; called by muse, mutect2, varscan2
- HERC5 | c.1732C>T p.H578Y | Missense Mutation (SNP) | VAF 6/90 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV99987659; called by muse, mutect2
- HIVEP2 | c.5686C>T p.Q1896* | Nonsense Mutation (SNP) | VAF 14/47 reads (30%) | catalogued as COSV99173274; called by muse, mutect2, varscan2
- HUWE1 | c.4477G>A p.D1493N | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.728); catalogued as COSV99472055; called by muse, mutect2, varscan2
- JRKL | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 31/170 reads (18%) | SIFT tolerated (0.26); PolyPhen benign (0.191); catalogued as COSV53595971, COSV99567283; called by muse, mutect2, varscan2
- KANSL1 | c.1970G>T p.R657L | Missense Mutation (SNP) | VAF 25/88 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); catalogued as COSV99294441; called by muse, mutect2, varscan2
- KANSL3 | c.430C>A p.L144I | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT tolerated (0.11); PolyPhen benign (0.03); catalogued as COSV100831091; called by muse, mutect2
- KDM7A | c.2376A>G p.G792= | Splice Region (SNP) | VAF 18/55 reads (33%) | catalogued as COSV99134389; called by muse, mutect2, varscan2
- KIDINS220 | c.4963G>A p.E1655K | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.426); catalogued as rs970613821, COSV56750940; called by muse, mutect2, varscan2
- KLK10 | c.395G>A p.R132Q | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.216); catalogued as rs1243714415, COSV100011063; called by muse, mutect2, varscan2
- LHFPL4 | c.539C>A p.A180D | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99805471; called by muse, mutect2, varscan2
- MAGI2 | c.433C>A p.H145N | Missense Mutation (SNP) | VAF 44/97 reads (45%) | SIFT deleterious (0); PolyPhen benign (0.296); catalogued as COSV100834413, COSV62691742; called by muse, mutect2, varscan2
- MMEL1 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.023); catalogued as rs781185434, COSV99983734; called by muse, varscan2
- MTMR7 | c.203G>A p.C68Y | Missense Mutation (SNP) | VAF 14/56 reads (25%) | SIFT tolerated (0.23); PolyPhen benign (0.048); catalogued as COSV99472342; called by muse, mutect2, varscan2
- NCKAP5L | c.1724C>A p.P575H | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as COSV100258718; called by muse, mutect2, varscan2
- NEFM | c.1411G>A p.E471K | Missense Mutation (SNP) | VAF 28/66 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as COSV55333117, COSV99647243; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.799G>A p.A267T (on ENST00000374531 / NM_001037293.2; = p.A299T on NM_053016.6) | Missense Mutation (SNP) | VAF 14/33 reads (42%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs140454806; called by muse, mutect2, varscan2
- POF1B | c.1578G>C p.K526N | Missense Mutation (SNP) | VAF 13/286 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99426618; called by muse, mutect2
- PPP1R12B | c.2023C>T p.R675C | Missense Mutation (SNP) | VAF 52/196 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs757445255, COSV51786790, COSV51789069; called by muse, mutect2, varscan2
- SCYL2 | c.730G>A p.E244K | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.36); PolyPhen benign (0.158); catalogued as rs76315511, COSV62568627, COSV62571551; called by muse, mutect2, varscan2
- SDF2 | c.217C>T p.R73W | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1050769710, COSV55931565; called by muse, mutect2, varscan2
- SEC14L5 | c.560G>A p.R187H | Missense Mutation (SNP) | VAF 21/52 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.031); catalogued as rs754852146, COSV52037163; called by muse, mutect2, varscan2
- TANC1 | c.3962G>A p.R1321Q | Missense Mutation (SNP) | VAF 18/62 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.98); catalogued as rs143668886, COSV99713796; called by muse, mutect2, varscan2
- TGM5 | c.974T>G p.L325W (on ENST00000220420 / NM_201631.4; = p.L243W on NM_004245.4) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1265157532, COSV99588956; called by muse, mutect2, varscan2
- TP63 | c.1694T>G p.F565C | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99286784; called by muse, mutect2, varscan2
- VWA8 | c.2999G>T p.R1000L | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.809); catalogued as rs202176681, COSV99864002; called by muse, mutect2, varscan2
- ZNF514 | c.760C>T p.H254Y | Missense Mutation (SNP) | VAF 31/81 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99727711; called by muse, mutect2, varscan2
- IGLV3-9 | c.308A>G p.D103G | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); called by muse, mutect2, varscan2
- CHEK2 | c.729C>G p.V243= (on ENST00000382580 / NM_001005735.2; = p.V200= on NM_007194.4) | Silent (SNP) | VAF 24/55 reads (44%) | catalogued as rs141685349; ClinVar: likely benign; called by muse, mutect2, varscan2
- CSMD1 | c.7470C>G p.L2490= (on ENST00000520002; = p.L2489= on NM_033225.6) | Silent (SNP) | VAF 16/43 reads (37%) | catalogued as rs1393920120, COSV100147232, COSV59308328; called by muse, mutect2, varscan2
- DGKK | c.1659G>A p.V553= | Silent (SNP) | VAF 36/87 reads (41%) | catalogued as COSV65707999; called by muse, mutect2, varscan2
- F8 | c.324G>A p.K108= | Silent (SNP) | VAF 26/74 reads (35%) | catalogued as COSV100811489; called by muse, mutect2, varscan2
- GPC3 | c.93G>A p.P31= | Silent (SNP) | VAF 39/94 reads (41%) | catalogued as rs781232455, COSV100892956; ClinVar: likely benign; called by muse, mutect2, varscan2
- ITGB4 | c.3054C>T p.D1018= | Silent (SNP) | VAF 21/40 reads (53%) | catalogued as rs775673910, COSV52323129, COSV99563961; called by muse, mutect2, varscan2
- MUC17 | c.4506C>A p.T1502= | Silent (SNP) | VAF 26/70 reads (37%) | catalogued as COSV100071617, COSV60280305; called by muse, mutect2, varscan2
- NDNF | c.486T>C p.Y162= | Silent (SNP) | VAF 23/57 reads (40%) | catalogued as COSV101113163; called by muse, mutect2, varscan2
- PCDHA7 | c.2229C>T p.S743= | Silent (SNP) | VAF 17/66 reads (26%) | catalogued as rs577159931, COSV65335396; called by muse, mutect2, varscan2
- SELENOV | c.1023G>A p.E341= | Silent (SNP) | VAF 8/30 reads (27%) | catalogued as COSV100112750; called by muse, mutect2, varscan2
- SHOX2 | c.414C>T p.I138= (on ENST00000441443 / NM_006884.3; = p.I162= on NM_003030.4) | Silent (SNP) | VAF 29/56 reads (52%) | catalogued as COSV101273783; called by muse, mutect2, varscan2
- SLC26A8 | c.828G>A p.A276= | Silent (SNP) | VAF 45/134 reads (34%) | catalogued as rs749676353, COSV100839455; called by muse, mutect2, varscan2
- SLC50A1 | c.642G>A p.R214= | Silent (SNP) | VAF 22/61 reads (36%) | catalogued as rs370960837; called by muse, mutect2, varscan2
- TNXB | c.3966C>T p.S1322= (on ENST00000647633; = p.S1075= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs372197657; called by muse, mutect2, varscan2
- AL132655.6 | chr20:58840832 C>T | 5'Flank (SNP) | VAF 21/62 reads (34%) | catalogued as rs1228262845, COSV100005312; called by muse, mutect2, varscan2
- CPLANE1 | c.*3739G>A | 3'UTR (SNP) | VAF 13/51 reads (25%) | catalogued as COSV99950433; called by muse, mutect2, varscan2
